Gene-level copy-number profile of tumor specimen REBC-ADJE-TTP1-A from REBC case REBC-ADJE, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADJE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cf492985-fadd-4338-81eb-62290270f031.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADJE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/edb9bb3d-9388-4f06-83c3-83b0281202e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 74; copy number 2: 58,229; copy number 3: 13; copy number 4: 80; copy number 5: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:114,392,790–114,511,203, 4 genes, copy number 5: TRIM33, AL035410.1, EIF2S2P5, Y_RNA.
- chr10:43,136,824–43,267,065, 3 genes, copy number 5: AC010864.1, CSGALNACT2, RASGEF1A.

Autosomal genes at a single copy (total copy number 1): 74. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
